Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4CA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4CA-01A (Primary Tumor).

[page 1 of 6]
Department of Pathology

Patient Name: [REDACTED]	Copath #: [REDACTED]
MRN: [REDACTED]	Service: Otolaryngology
DOB: [REDACTED]	Collected: [REDACTED]
Gender: [REDACTED]	Visit #: [REDACTED]
HCN: [REDACTED]	Location: [REDACTED]
Ordering MD: [REDACTED]	Facility: [REDACTED]
	Resulted: [REDACTED]

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: left external jugular node
2. Soft Tissue: left level 1
3. Soft Tissue: left level 2A
4. Soft Tissue: left level 3
5. Soft Tissue left level 4
6. Neck: left partial glossectomy,
7. Soft Tissue: anterior mucosal margin
8. Oral Cavity: floor of mouth
9. Oral Cavity: dorsal tongue margin,

ICD-O-3
carcinoma, squamous cell, NOS
8070/3
Site: Tongue, ventral surface, NOS
C02.2
JW 9/26/12

DIAGNOSIS

1. Left external jugular nodes:
- Two lymph nodes and salivary tissue, negative for malignancy (0/2).
2. Left neck; level I:
- Four lymph nodes, negative for malignancy (0/4).
- Submandibular gland with no pathologic abnormality.
3. Left neck; level IIA:
- Nine lymph nodes, negative for malignancy (0/9).
4. Left neck; level III:
- Seven lymph nodes, negative for malignancy (0/7).
5. Left neck; level IV:
- Three lymph nodes, negative for malignancy (0/3).
6. Left partial glossectomy:
- Squamous cell carcinoma, moderately differentiated.
- a. Maximum tumour dimension is 2.5 cm.
- b. Tumour thickness is 0.6 cm.
- c. No perineural invasion is identified.

[page 2 of 6]
d. No lymphovascular invasion is identified.

Status: complete

Page: 1 of 5

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

e. Margins of resection, negative for tumour (> 0.5 cm). The closest margin to tumour is anterior at 0.6 cm.

7. Anterior mucosal margin:
- Negative for malignancy.

8. Floor of mouth:
- Negative for malignancy.

9. Dorsal tongue margin:
- Negative for malignancy.

SYNOPTIC DATA

Specimen:
otherwise specified (NOS)

I-IV)
Received:
Procedure:
glossectomy.

neck dissection (levels I-IV).
Specimen Size:

Specimen Laterality:
Tumor Site:

Tumor Focality:
Tumor Size:

Ventral surface of tongue, not

Floor of mouth, NOS
Other: Left neck dissection (levels

Fresh
Glossectomy: Left partial

Neck (lymph node) dissection: Left

Greatest dimension: 5.3 cm
Additional dimension: 4.3 cm
Additional dimension: 0.8 cm
Left

Ventral surface of tongue, NOS
Floor of mouth, NOS
Single focus
Greatest dimension: 2.5 cm
Additional dimension: 2.4 cm
Additional dimension: 0.6 cm

[page 3 of 6]
Histologic Type: Squamous cell carcinoma, conventional
Histologic Grade: G2: Moderately differentiated
Margins: Margins uninvolved by invasive
carcinoma
Distance from closest margin: 0.6 cm

Status: complete

Page: 2 of 5

Patient, Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

is not applicable	Margin(s): Anterior margin.
Lymph-Vascular Invasion:	Margin status for carcinoma in situ
Perineural Invasion:	Not identified
Lymph Nodes, Extranodal Extension:	Not identified
TNM Descriptors:	Not identified
Primary Tumor (pT):	Not applicable
more than 4 cm in greatest dimension	pT2: Tumor more than 2 cm but not
Regional Lymph Nodes (pN):	pN0: No regional lymph node
metastasis	
examined: 25	Number of regional lymph nodes
involved: 0	Number of regional lymph nodes
Distant Metastasis (pM):	Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1 The specimen is labeled with the patient's name and "left external

[page 4 of 6]
jugular node". It consists of portion of fibroadipose tissue measuring 1.5 x 0.9 x 1cm. Multiple lymph nodes ranging from 0.2 to 0.8cm are identified. Representative sections are submitted.

1A 1 node

1B larger node bisected

2. The specimen is labeled with the patient's name and "left level 1". It consists of portion of fibroadipose tissue measuring 6 x 4.5 x 3 cm. Multiple lymph nodes ranging from 0.5 to 1.4 cm are identified. The grossly unremarkable submandibular gland is identified measuring 5 x 3.2 x 2.5 cm. Representative sections are submitted.

2A 2 nodes

2B 1 node

Status: complete

Page: 3 of 5

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location:	Resulted: [REDACTED]
Gender: [REDACTED]	Facility:	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

2C 1 node bisected

2D submandibular gland

3. The specimen is labeled with the patient's name and "left level 2A". It consists of portion of fibroadipose tissue measuring 6 x 3 x 1.5 cm. Multiple lymph nodes ranging from 0.2 to 1.1 cm are identified. Representative sections are submitted.

3A multiple nodes

3B 2 nodes

3C 4 nodes

4. The specimen is labeled with the patient's name and "left level 3". It consists of portion of fibroadipose tissue measuring 3.5 x 2.5 x 1 cm. Multiple lymph nodes ranging from 0.1 to 1.3 cm are identified. Representative sections are submitted.

4A-4B multiple nodes

5. The specimen is labeled with the patient's name and "left level 4". It consists of portion of fibroadipose tissue measuring 5 x 1.7 x 1 cm. Multiple lymph nodes ranging from 0.1 to 0.7 cm are identified. Representative sections are submitted.

5A multiple nodes

[page 5 of 6]
6. The specimen is labeled the patient's name and as "left partial glossectomy". It consists of a portion of left tongue measuring 4.3 SI x 0.8 ML x 5.3 AP cm. There is one anterior suture orientation. There is an ulcerated tumor involving the ventral surface of the tongue/ floor of mouth. The tumor measures 2.5 SI x 0.6 ML x 2.4 AP cm. The tumor is 0.6 cm from the anterior margin. It is located at 1.0 cm from the lateral margin, 0.7 cm from the deep/medial margin, and 2.0 cm from the posterior margin. Representative sections are submitted.

6A anterior margin frozen section

6B anterior margin

6C posterior margin

6D deep medial margin and tumor

6E superior margin

6F lateral margin

6G tumor and deep medial margin

7. The specimen is labeled with the patient's name and as "anterior mucosal margin". It consists of a fragment of tissue measuring 1.7 x 0.5

Status: complete

Page: 4 of 5

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

x 0.2 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "floor of mouth". It consists of a fragment of tissue measuring 1.5 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

8A frozen section control

9. The specimen is labeled with the patient's name and as "dorsal tongue margin". It consists of a fragment of tissue measuring 2.2 x 0.4 x 0.2cm. The specimen is submitted in toto for frozen section.

9A frozen section control

[page 6 of 6]
QUICK SECTION

6. Left partial glossectomy suture anterior: 6A: sagittal section including closest mucosal margin and deep margin: negative for carcinoma

7. Anterior mucosal margin: 7A: negative for carcinoma: negative for carcinoma

8. Floor of mouth margin: 8A: negative for carcinoma: negative for carcinoma

9. Dorsal tongue margin: 9A: negative for carcinoma.

Case called in to

Status: complete

Page: 5 of 5

8/24/12

Source: NCI Genomic Data Commons file 421f0ada-c519-4872-b279-b5e11bd25379 (TCGA-CQ-A4CA.B5B00BA7-3720-417A-9BE9-DFF9EABC32B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).